Somatic mutation profile of tumor specimen TCGA-QR-A702-01A (aliquot TCGA-QR-A702-01A-11D-A35D-08) from TCGA case TCGA-QR-A702, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Extra-adrenal paraganglioma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 75.0 years (27,395 days).
Specimen TCGA-QR-A702-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2fd4bb7a-f09b-43b3-9f6e-d617864ec650.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A702-10A (Blood Derived Normal), aliquot TCGA-QR-A702-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0ffe2a3-a13e-4938-83db-8034cacbe580

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF10L | c.401T>G p.V134G | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- BCAR1 | c.2113G>A p.E705K | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CRHR2 | c.935C>G p.T312S | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- NF1 | c.1947_1948insG p.L650Vfs*20 | Frame Shift Ins (INS) | VAF 39/65 reads (60%) | called by mutect2, pindel, varscan2
- SLC66A1 | c.138T>G p.I46M | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- AMER1 | c.207G>T p.L69= | Silent (SNP) | VAF 39/73 reads (53%) | called by muse, mutect2, varscan2
- MXRA5 | c.5178C>T p.S1726= | Silent (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2, varscan2
